Somatic mutation profile of tumor specimen TCGA-GL-7773-01A (aliquot TCGA-GL-7773-01A-11D-2136-08) from TCGA case TCGA-GL-7773, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.6 years (23,239 days).
Specimen TCGA-GL-7773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9aa0677-f5a1-4457-a701-d45849572a23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-7773-10A (Blood Derived Normal), aliquot TCGA-GL-7773-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f00fba64-6845-472e-9c99-ce8b2b2c36d2

The open-access MAF lists 129 somatic variants for this specimen: 101 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 27, Nonsense Mutation 9, Frame Shift Del 7, Frame Shift Ins 4, In Frame Del 2, Splice Region 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM20 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56455187; called by muse, mutect2, varscan2
- ANO6 | c.1954G>T p.D652Y | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57662059; called by muse, mutect2, varscan2
- ARHGEF3 | c.685A>C p.K229Q | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV56327687; called by muse, mutect2, varscan2
- AXIN1 | c.2517G>T p.E839D | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51988370; called by muse, mutect2, varscan2
- BAHD1 | c.2308T>C p.F770L | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60378920; called by muse, mutect2, varscan2
- CA13 | c.583T>G p.Y195D | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58798008; called by muse, mutect2, varscan2
- CDC16 | c.1242G>T p.Q414H | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV52959914; called by muse, mutect2, varscan2
- CDC20 | c.1322-1G>A p.X441_splice | Splice Site (SNP) | VAF 56/134 reads (42%) | catalogued as COSV60522229; called by muse, mutect2, varscan2
- CDKAL1 | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51184226; called by muse, mutect2, varscan2
- CDKL2 | c.691A>T p.K231* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV56733728, COSV56734801; called by muse, mutect2, varscan2
- CELSR2 | c.5340C>A p.S1780R | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54773299; called by muse, mutect2, varscan2
- CHD1 | c.4918C>T p.H1640Y | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.042); catalogued as rs1480645533, COSV52340984; called by muse, mutect2, varscan2
- CNNM4 | c.1269C>A p.Y423* | Nonsense Mutation (SNP) | VAF 69/189 reads (37%) | catalogued as COSV65661123; called by muse, mutect2, varscan2
- COG1 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1189503554, COSV55430066; called by muse, mutect2, varscan2
- COL11A2 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1562387094, COSV59497759; called by muse, mutect2, varscan2
- DBT | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64495581; called by muse, mutect2, varscan2
- DHX33 | c.1661C>A p.S554Y | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56579338; called by muse, mutect2, varscan2
- DHX9 | c.3670G>C p.G1224R | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.465); catalogued as COSV62360021; called by muse, mutect2, varscan2
- DMXL2 | c.4671A>C p.S1557= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as COSV51847843; called by muse, mutect2, varscan2
- DROSHA | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV60777111, COSV60779315; called by muse, mutect2, varscan2
- EFR3A | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs765471153, COSV54458190; called by muse, mutect2, varscan2
- ELOA | c.1640A>C p.E547A | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV69310448; called by muse, mutect2, varscan2
- FAR2 | c.1092T>A p.Y364* | Nonsense Mutation (SNP) | VAF 133/333 reads (40%) | catalogued as COSV51726133; called by muse, mutect2, varscan2
- FARSA | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV104406260, COSV58905082; called by muse, mutect2, varscan2
- FLG | c.11339G>C p.R3780T | Missense Mutation (SNP) | VAF 241/687 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64242728; called by muse, mutect2, varscan2
- FLII | c.2945G>A p.C982Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV57498502; called by muse, mutect2, varscan2
- FLT4 | c.3907G>A p.G1303S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV56110827; called by muse, mutect2, varscan2
- GLYR1 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58927348; called by muse, mutect2, varscan2
- HELZ | c.2876A>C p.Q959P | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62378823; called by muse, mutect2, varscan2
- HELZ | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 63/181 reads (35%) | catalogued as COSV62378829; called by muse, mutect2, varscan2
- HERC2 | c.8702A>T p.D2901V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55327264; called by muse, mutect2, varscan2
- HOXB7 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV53310626; called by muse, mutect2, varscan2
- HSPA2 | c.606C>A p.D202E | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55969881; called by muse, varscan2
- IGSF9B | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs766517121, COSV58068525; called by muse, mutect2, varscan2
- IQCF2 | c.412T>C p.C138R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60761529; called by muse, mutect2
- ITGAM | c.2803G>T p.V935F (on ENST00000648685 / NM_001145808.2; = p.V934F on NM_000632.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs199790913; called by muse, mutect2, varscan2
- KIAA1109 | c.8949G>C p.M2983I | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52676205; called by muse, mutect2, varscan2
- KLRK1 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | catalogued as COSV53698750, COSV99555300; called by muse, mutect2, varscan2
- KRT4 | c.767T>A p.V256E | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV53407743, COSV53407776; called by muse, mutect2, varscan2
- LGALS8 | c.341T>A p.F114Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV53025098; called by muse, mutect2, varscan2
- LRRK2 | c.7389A>G p.L2463= | Splice Region (SNP) | VAF 31/90 reads (34%) | catalogued as rs1477718182, COSV54155617; called by muse, mutect2, varscan2
- MCCC1 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55609143; called by muse, mutect2, varscan2
- MEGF6 | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV62993338; called by muse, mutect2, varscan2
- MICALL1 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.191); catalogued as COSV53241040; called by muse, mutect2, varscan2
- MRPS14 | c.46A>G p.M16V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750457789, COSV62880358; called by muse, mutect2, varscan2
- MTRR | c.628G>T p.E210* (on ENST00000264668; = p.E183* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52944326; called by muse, mutect2, varscan2
- MYO5C | c.4408C>A p.P1470T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV55907307; called by muse, mutect2, varscan2
- NLRP4 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.138); catalogued as COSV56715241; called by muse, mutect2, varscan2
- NPC2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV53143591; called by muse, mutect2
- NRAP | c.3807C>A p.D1269E (on ENST00000359988 / NM_001322945.2; = p.D1234E on NM_006175.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as COSV63491131; called by muse, varscan2
- NRAP | c.3806A>T p.D1269V (on ENST00000359988 / NM_001322945.2; = p.D1234V on NM_006175.4) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63491138; called by muse, varscan2
- NRAP | c.3805G>T p.D1269Y (on ENST00000359988 / NM_001322945.2; = p.D1234Y on NM_006175.4) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63491144; called by muse, varscan2
- NRXN3 | c.2339G>A p.R780Q (on ENST00000335750 / NM_001330195.2; = p.R407Q on NM_004796.6) | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs367857290, COSV59727532; called by muse, mutect2, varscan2
- NTAN1 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55074525; called by muse, mutect2, varscan2
- NUP214 | c.1450T>A p.F484I | Missense Mutation (SNP) | VAF 152/451 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV63910125; called by muse, mutect2, varscan2
- PC | c.3057C>G p.H1019Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV58992965; called by muse, mutect2, varscan2
- PCDHGB2 | c.2027G>A p.S676N | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV53962087; called by muse, mutect2, varscan2
- PFKFB3 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 66/202 reads (33%) | PolyPhen benign (0); catalogued as COSV100432171; called by muse, varscan2
- PFKFB3 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 66/199 reads (33%) | PolyPhen benign (0.003); catalogued as COSV100432175; called by muse, varscan2
- PFKFB3 | c.417T>A p.H139Q | Missense Mutation (SNP) | VAF 66/196 reads (34%) | PolyPhen benign (0); catalogued as COSV100432178, COSV57986795; called by muse, varscan2
- PHKB | c.1833G>T p.M611I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54523298; called by muse, mutect2, varscan2
- PLS3 | c.1798G>C p.V600L | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV56779244; called by muse, mutect2, varscan2
- PREP | c.841A>T p.N281Y (on ENST00000369110; = p.N347Y on NM_002726.5) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV64870454; called by muse, mutect2, varscan2
- PRPF18 | c.523T>A p.S175T | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60725519; called by muse, mutect2, varscan2
- PRRC2C | c.6020T>C p.I2007T (on ENST00000367742; = p.I2005T on NM_015172.4) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV58906516; called by muse, mutect2, varscan2
- PRSS3 | c.119T>C p.L40P (on ENST00000361005 / NM_007343.4; = p.L148P on NM_002771.3) | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV61556413; called by muse, mutect2, varscan2
- PSME2 | c.666C>A p.S222R | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV104370920, COSV52824407; called by muse, mutect2, varscan2
- PUM1 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 113/332 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57086321; called by muse, mutect2, varscan2
- QRICH2 | c.3781G>T p.G1261C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53153988; called by muse, mutect2, varscan2
- RABEP2 | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62869721; called by muse, mutect2, varscan2
- RASGRP3 | c.1340G>C p.S447T (on ENST00000402538 / NM_001349975.2; = p.S446T on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.599); catalogued as COSV67822412; called by muse, mutect2, varscan2
- RNF40 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV61215093; called by muse, mutect2, varscan2
- RP1L1 | c.4625G>T p.R1542L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV66756008; called by muse, varscan2
- RSBN1 | c.2036C>G p.P679R | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54732714; called by muse, mutect2, varscan2
- SALL4 | c.1125C>G p.D375E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.988); catalogued as COSV53852880; called by muse, mutect2, varscan2
- SEMA3A | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV54873049; called by muse, mutect2, varscan2
- SEMA4D | c.603T>A p.Y201* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV59395800; called by muse, mutect2, varscan2
- SH2B1 | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1045024791, COSV59463528; called by muse, mutect2, varscan2
- STRN | c.600A>C p.K200N | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55748516; called by muse, mutect2, varscan2
- SYNE3 | c.2417T>C p.F806S | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100516035, COSV62079958; called by muse, mutect2, varscan2
- TANGO6 | c.2025A>T p.R675S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55766453; called by muse, mutect2, varscan2
- TNR | c.1697C>G p.P566R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54889355, COSV54904110; called by muse, mutect2, varscan2
- WDR44 | c.342T>G p.D114E | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV54164353; called by muse, mutect2, varscan2
- ZNF599 | c.1533A>T p.E511D | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61396377; called by muse, mutect2
- ZNF599 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 68/169 reads (40%) | catalogued as COSV61396391; called by muse, mutect2
- ZNF770 | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1194665180, COSV62544397; called by muse, mutect2, varscan2
- AHNAK2 | c.13721del p.D4574Afs*2 | Frame Shift Del (DEL) | VAF 81/302 reads (27%) | called by mutect2, pindel, varscan2
- ARMCX1 | c.821dup p.L274Ffs*12 | Frame Shift Ins (INS) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- CHL1 | c.1601dup p.L534Ffs*4 (on ENST00000397491 / NM_001253387.1; = p.L550Ffs*4 on NM_006614.4) | Frame Shift Ins (INS) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- CLEC1B | c.594del p.H199Ifs*16 | Frame Shift Del (DEL) | VAF 62/194 reads (32%) | called by mutect2, pindel, varscan2
- F12 | c.1778_1779del p.R593Qfs*38 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- FUT4 | c.1348_1350del p.F450del | In Frame Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- LRTM1 | c.701_706del p.L234_A236delinsP | In Frame Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.830G>T p.S277I | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MTCL1 | c.3719_3720insT p.W1241Lfs*48 (on ENST00000306329 / NM_001378206.1; = p.W922Lfs*48 on NM_015210.4) | Frame Shift Ins (INS) | VAF 12/25 reads (48%) | called by mutect2, pindel*, varscan2
- PBX1 | c.932_933insATAGT p.T312* | Frame Shift Ins (INS) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- PRPF38A | c.884_886dup p.K295_S296ins* | Nonsense Mutation (INS) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- SEC14L5 | c.260_269del p.N87Rfs*19 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2*
- SKAP1 | c.206del p.D69Vfs*31 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- STIL | c.3645del p.A1216Lfs*3 | Frame Shift Del (DEL) | VAF 61/179 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2200_2201del p.M734Efs*6 (on ENST00000474710 / NM_001164342.2; = p.M661Efs*6 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 49/148 reads (33%) | called by mutect2, pindel, varscan2
- ABL1 | c.1809G>A p.L603= | Silent (SNP) | VAF 88/212 reads (42%) | catalogued as COSV100584278; called by mutect2, varscan2
- ANKRD44 | c.1683A>G p.E561= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV56556819; called by muse, mutect2, varscan2
- ATP2B3 | c.3042C>T p.F1014= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs181539158, COSV54844419, COSV54849515; called by muse, mutect2, varscan2
- ATP7B | c.480C>T p.S160= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV54439397; called by muse, mutect2, varscan2
- BACH2 | c.1611C>T p.P537= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs1251444839, COSV57594798; called by muse, mutect2, varscan2
- BEGAIN | c.111C>T p.H37= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV62068985; called by muse, mutect2, varscan2
- C3orf14 | c.243T>A p.V81= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as COSV51706892; called by muse, mutect2, varscan2
- CAMP | c.501T>C p.L167= (on ENST00000296435; = p.L164= on NM_004345.5) | Silent (SNP) | VAF 76/205 reads (37%) | catalogued as COSV56482041; called by muse, mutect2, varscan2
- CARF | c.2097A>G p.Q699= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV57547930; called by muse, mutect2, varscan2
- CHIA | c.1305C>T p.N435= (on ENST00000343320; = p.N327= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs756720776, COSV58475712; called by muse, mutect2, varscan2
- COL9A1 | c.591C>T p.D197= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as rs1306409534, COSV61833363; called by muse, mutect2, varscan2
- CPOX | c.720T>A p.A240= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99939147; called by muse, varscan2
- CUBN | c.8457T>C p.P2819= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV64717480; called by muse, mutect2, varscan2
- DRD2 | c.297G>A p.E99= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV60758704; called by muse, mutect2, varscan2
- FLRT1 | c.1896G>A p.E632= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as COSV55361399; called by muse, mutect2, varscan2
- HSPA2 | c.558G>A p.L186= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs762698094, COSV55969872; called by muse, varscan2
- MPEG1 | c.1953T>A p.G651= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as COSV57091479; called by muse, mutect2, varscan2
- PLSCR2 | c.747G>A p.K249= (on ENST00000497985 / NM_001199978.1; = p.K176= on NM_020359.2) | Silent (SNP) | VAF 83/208 reads (40%) | catalogued as rs982206060, COSV60861694; called by muse, mutect2, varscan2
- RGS18 | c.189C>T p.S63= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV66507185; called by muse, mutect2, varscan2
- SAMD15 | c.885G>A p.K295= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV53626589, COSV99374991; called by muse, mutect2, varscan2
- SIPA1L2 | c.1272T>A p.I424= | Silent (SNP) | VAF 94/237 reads (40%) | catalogued as COSV53391722; called by muse, mutect2, varscan2
- SLC22A13 | c.768C>A p.T256= | Silent (SNP) | VAF 101/289 reads (35%) | catalogued as COSV61291229; called by muse, mutect2, varscan2
- SLC25A13 | c.894G>A p.E298= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV55708272; called by muse, mutect2, varscan2
- STX17 | c.702G>A p.V234= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV52284017; called by muse, mutect2
- THOC2 | c.1057T>C p.L353= | Silent (SNP) | VAF 62/157 reads (39%) | catalogued as COSV55547423; called by muse, mutect2, varscan2
- TINF2 | c.702C>G p.A234= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV57469247; called by muse, mutect2, varscan2
- TTN | c.14460T>C p.F4820= (on ENST00000591111; = p.F3893= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/219 reads (35%) | catalogued as rs1560836829, COSV60107944; called by muse, mutect2, varscan2
- PML | c.1710+1082G>A | Intron (SNP) | VAF 38/123 reads (31%) | catalogued as COSV99167506; called by muse, mutect2, varscan2
